Somatic mutation profile of tumor specimen TCGA-XF-A9SI-01A (aliquot TCGA-XF-A9SI-01A-11D-A391-08) from TCGA case TCGA-XF-A9SI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 73.2 years (26,719 days).
Specimen TCGA-XF-A9SI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08425cd4-7ca4-4f42-921c-d10a59789c33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SI-10A (Blood Derived Normal), aliquot TCGA-XF-A9SI-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59b3d371-c9ff-465b-bf35-9539a3fbfd9e

The open-access MAF lists 353 somatic variants for this specimen: 258 protein-altering or splice-affecting, 90 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 227, Silent 90, Nonsense Mutation 24, Splice Site 6, Intron 3, RNA 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2107-1G>C p.X703_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as rs587778860, CS125752, COSV57297199, COSV57304025; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955806762, COSV59388460; called by muse, mutect2, varscan2
- ABCC12 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as rs773415702, COSV60914826; called by muse, mutect2
- ABHD12B | c.424A>G p.I142V (on ENST00000337334 / NM_001206673.2; = p.I65V on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV61569729; called by muse, mutect2
- ABL2 | c.2069C>T p.S690L (on ENST00000502732 / NM_007314.4; = p.S675L on NM_005158.5) | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.124); catalogued as COSV61016444; called by muse, mutect2, varscan2
- ADCY3 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV53168984; called by muse, mutect2, varscan2
- AK5 | c.1045G>A p.D349N (on ENST00000354567 / NM_174858.3; = p.D323N on NM_012093.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60975135; called by muse, mutect2, varscan2
- ALOX15 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV53398528; called by muse, mutect2
- AMER1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.817); catalogued as COSV57657110, COSV57662413; called by muse, mutect2, varscan2
- ANKLE1 | c.1106C>T p.S369F (on ENST00000394458; = p.S315F on NM_152363.6) | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV63921052; called by muse, mutect2
- APCS | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54818495; called by muse, mutect2
- APOB | c.13114C>G p.Q4372E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99263256; called by muse, mutect2
- APOO | c.233G>A p.C78Y | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV64870749; called by muse, mutect2
- ARCN1 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as COSV50615733; called by muse, mutect2, varscan2
- ARHGEF16 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65682410; called by muse, mutect2, varscan2
- ARID3B | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60558077; called by muse, mutect2
- ASTN1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV62499094; called by muse, mutect2
- ATF4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1438372076, COSV100307506; called by muse, mutect2
- ATM | c.8138G>A p.R2713K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs876659351, COSV53739675; ClinVar: uncertain significance; called by muse, mutect2
- ATN1 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.167); catalogued as rs1555143671, COSV100755634, COSV100756012; called by muse, mutect2
- ATR | c.4748C>G p.S1583C | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV63387687, COSV63392180; called by muse, mutect2
- B2M | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as COSV62563077, COSV62564921; called by muse, mutect2, varscan2
- BABAM2 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 8/176 reads (5%) | catalogued as COSV100567183; called by muse, mutect2
- BAZ2B | c.3364C>G p.Q1122E | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54276024, COSV54276140; called by muse, mutect2
- BCAT1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99678003; called by muse, mutect2
- BCHE | c.1647C>G p.F549L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); catalogued as COSV52258220; called by muse, mutect2, varscan2
- BCORL1 | c.1595C>G p.S532C | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54399024; called by muse, mutect2, varscan2
- BCORL1 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as COSV54399077; called by muse, mutect2, varscan2
- BLZF1 | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as COSV61393925, COSV61394008; called by muse, mutect2, varscan2
- BMX | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100564336, COSV59591919; called by muse, mutect2
- BNIP3 | c.536C>G p.S179* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100893133; called by muse, mutect2
- CAD | c.5276C>T p.T1759I | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99254310; called by muse, mutect2
- CADPS2 | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV57356265; called by muse, mutect2
- CALD1 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62649224; called by muse, mutect2, varscan2
- CAMK1G | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50523122; called by muse, mutect2
- CARD6 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1348689256, COSV54566986; called by muse, mutect2, varscan2
- CCDC6 | c.585G>C p.L195F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54057446; called by muse, mutect2, varscan2
- CCDC82 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV53594033; called by muse, mutect2, varscan2
- CCT7 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99240491; called by muse, mutect2
- CD109 | c.2592C>G p.I864M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54651791; called by muse, mutect2, varscan2
- CD163 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.402); catalogued as COSV63133901; called by muse, mutect2, varscan2
- CD180 | c.543G>C p.Q181H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV56518535; called by muse, mutect2
- CDH2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.992); catalogued as COSV52284475, COSV52298127; called by muse, mutect2, varscan2
- CHD6 | c.4196G>C p.R1399T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100950496; called by muse, mutect2
- CIC | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV50600470; called by muse, mutect2, varscan2
- CIC | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs777194374, COSV50600646; called by muse, mutect2, varscan2
- CKAP5 | c.4283C>G p.S1428C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV56369455; called by muse, mutect2, varscan2
- CLTA | c.628G>A p.E210K (on ENST00000242285 / NM_007096.4; = p.E180K on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54255037; called by muse, mutect2, varscan2
- COPB1 | c.2654C>G p.S885C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs373344919; called by muse, mutect2, varscan2
- CSMD2 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as COSV53882759, COSV53950992; called by muse, mutect2
- CTNND1 | c.1091G>C p.R364T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62384245; called by muse, mutect2
- CTTNBP2 | c.4207C>G p.L1403V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200259226, COSV50413287; called by muse, mutect2, varscan2
- CWC22 | c.1102C>G p.H368D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55429658; called by muse, mutect2, varscan2
- CXorf38 | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV59947797; called by muse, mutect2, varscan2
- DAB2 | c.1541G>A p.W514* | Nonsense Mutation (SNP) | VAF 6/120 reads (5%) | catalogued as COSV100297752; called by muse, mutect2
- DCT | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV65469760; called by muse, mutect2
- DENND5B | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100170777; called by muse, mutect2
- DGKK | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs187535842, COSV65707595; called by muse, mutect2, varscan2
- DIP2B | c.960G>C p.Q320H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as COSV56586178; called by muse, mutect2, varscan2
- DNAAF4 | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as rs1322566644, COSV100336543; called by muse, mutect2, varscan2
- DNAJC21 | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57761145; called by muse, mutect2, varscan2
- DOP1B | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67693874; called by muse, mutect2
- DPF2 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV99361303; called by muse, mutect2
- DPY19L1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550671520, COSV60582904; called by muse, mutect2, varscan2
- DRG1 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV58919029; called by muse, mutect2, varscan2
- EHD2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); catalogued as COSV99621560; called by muse, mutect2
- EIF2B5 | c.709-1G>A p.X237_splice (on ENST00000647909; = p.X229_splice on NM_003907.3) | Splice Site (SNP) | VAF 15/101 reads (15%) | catalogued as COSV56604908, COSV56605874; called by muse, mutect2, varscan2
- EIF2B5 | c.1023G>C p.Q341H (on ENST00000647909; = p.Q333H on NM_003907.3) | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56604916; called by muse, mutect2, varscan2
- EIF4A1 | c.955C>A p.R319S | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51512462, COSV99548666; called by muse, mutect2
- EIF4E | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV55187800; called by muse, mutect2, varscan2
- ELF4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57451686; called by muse, mutect2
- EMILIN3 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1464556342, COSV60036996; called by muse, mutect2, varscan2
- EP300 | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54330276; called by muse, mutect2
- EP400 | c.4730C>T p.T1577I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV57776215; called by muse, mutect2
- EPG5 | c.2172C>G p.F724L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV56351454; called by muse, mutect2, varscan2
- EPPK1 | c.5506G>C p.E1836Q | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV73261580; called by muse, mutect2
- EXOSC5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV54197916; called by muse, mutect2, varscan2
- F13B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558311941, COSV66374470; called by muse, mutect2
- FANCB | c.1520C>G p.S507* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | catalogued as COSV100146321; called by muse, mutect2
- FANCD2 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1174526149, COSV55038567; called by muse, mutect2, varscan2
- FBN1 | c.8611C>G p.H2871D | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100353934; called by muse, mutect2
- FBXO7 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56679386; called by muse, mutect2
- FCRL2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100829802, COSV100830017, COSV63833700; called by muse, mutect2
- FGD4 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.188); catalogued as COSV56785694, COSV99847085; called by muse, mutect2, varscan2
- FHOD3 | c.3376C>G p.L1126V (on ENST00000359247 / NM_001281739.3; = p.L1143V on NM_025135.5) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57177187; called by muse, mutect2
- FNBP4 | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV55449683; called by muse, mutect2, varscan2
- FNIP2 | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV52441327; called by muse, mutect2
- FOXE1 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs1399563681, COSV100909834; called by muse, mutect2
- FOXM1 | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV61206427; called by muse, mutect2
- FSCN3 | c.1367G>C p.C456S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.388); catalogued as COSV99756735, COSV99757011; called by muse, mutect2
- GAS2L1 | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as rs769868490, COSV53330808; called by muse, mutect2, varscan2
- GAS2L1 | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1195663734, COSV53330817; called by muse, varscan2
- GCC2 | c.3953C>T p.S1318F | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59177463; called by muse, mutect2
- GK2 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); catalogued as rs777950818, COSV62627425; called by muse, mutect2, varscan2
- GK5 | c.412-1G>C p.X138_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV67486016; called by muse, mutect2, varscan2
- GNAI1 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV63523651; called by muse, mutect2, varscan2
- GPRC5A | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV50007979; called by muse, mutect2, varscan2
- GRIK4 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV70803551; called by muse, mutect2, varscan2
- HAL | c.1871G>A p.R624K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54118542; called by muse, mutect2
- HDGFL1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV57752277; called by muse, mutect2, varscan2
- HERC1 | c.7068C>T p.I2356= | Splice Region (SNP) | VAF 8/156 reads (5%) | catalogued as COSV71248529; called by muse, mutect2
- HIP1R | c.2627C>G p.S876C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53442486; called by muse, mutect2, varscan2
- HMCN1 | c.9724C>G p.Q3242E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs1368316791, COSV54911046, COSV99635830; called by muse, mutect2, varscan2
- HPS3 | c.1896G>C p.Q632H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1338910310, COSV56055325; called by muse, mutect2
- HRC | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1450875674, COSV53257107; called by muse, varscan2
- HS1BP3 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.348); catalogued as COSV58313551; called by muse, mutect2, varscan2
- IDH3A | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 9/182 reads (5%) | catalogued as COSV99356962; called by muse, mutect2
- INPP4A | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50798588; called by muse, mutect2
- INSC | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV65411333; called by muse, mutect2
- ITIH2 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.65); PolyPhen probably damaging (1); catalogued as COSV100623122; called by muse, mutect2
- ITPR2 | c.4084G>C p.E1362Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as COSV67271137; called by muse, mutect2
- ITPRID2 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100237809; called by muse, mutect2
- ITPRIPL2 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67347803; called by muse, mutect2, varscan2
- KATNA1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | catalogued as COSV100167593; called by muse, mutect2
- KATNA1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV59502959; called by muse, mutect2
- KCNB1 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65569012; called by muse, mutect2
- KCNS3 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV58407568; called by muse, mutect2, varscan2
- KDM5A | c.1440T>G p.F480L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66993615; called by muse, mutect2, varscan2
- KDM5B | c.3992C>G p.S1331* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | catalogued as COSV52507165; called by muse, mutect2
- KEL | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV62333141, COSV62335839; called by muse, mutect2, varscan2
- KIAA0100 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV66494097; called by muse, mutect2, varscan2
- KIF24 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191376096, COSV61456155; called by muse, mutect2, varscan2
- KLRF1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54381179; called by muse, mutect2
- KRTAP13-4 | c.465C>G p.F155L | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as COSV61879554; called by muse, mutect2
- LARP6 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV54580673; called by muse, mutect2
- LCMT2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2, varscan2
- LMBR1L | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57268150; called by muse, mutect2
- LRRK2 | c.2539C>G p.Q847E | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV54157657; called by muse, varscan2
- LSM14A | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.968); catalogued as COSV70885284; called by muse, varscan2
- MAGEC3 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as COSV68923840; called by muse, mutect2
- MAGOHB | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV57898681; called by muse, mutect2, varscan2
- MARK1 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65068486; called by muse, mutect2, varscan2
- MATN2 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs369974305; called by muse, mutect2, varscan2
- MGA | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 7/144 reads (5%) | catalogued as rs1225212904, COSV54950572, COSV54952145; called by muse, mutect2
- MGAT4C | c.1220A>T p.H407L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV59830038, COSV59833954; called by muse, mutect2, varscan2
- MIA3 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV60514278; called by muse, mutect2
- MME | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV64708254, COSV64708708; called by muse, mutect2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2
- MTHFD1L | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV66208605; called by muse, mutect2
- MUC16 | c.32369C>G p.S10790* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV101197798, COSV67480339; called by muse, mutect2
- MYBPC1 | c.197G>T p.G66V (on ENST00000550270 / NM_206820.2; = p.G91V on NM_002465.4) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100637705, COSV62255307; called by muse, mutect2
- NAP1L1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | catalogued as COSV99673634; called by muse, mutect2, varscan2
- NCOR1 | c.2708C>G p.S903* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV51970050; called by muse, mutect2
- NEB | c.13885C>T p.Q4629* | Nonsense Mutation (SNP) | VAF 7/180 reads (4%) | catalogued as COSV99414117; called by muse, mutect2
- NEK2 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100878523, COSV65356285; called by muse, mutect2, varscan2
- NEXMIF | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV50042311, COSV99280176; called by muse, mutect2, varscan2
- NF2 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV58522724, COSV58525454; called by muse, mutect2
- NIN | c.3660G>C p.K1220N | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55381402; called by muse, mutect2
- NIN | c.3448G>C p.D1150H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV55395370; called by muse, mutect2
- NKTR | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV51772949; called by muse, mutect2
- NOP14 | c.2427G>C p.K809N | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58625941; called by muse, mutect2, varscan2
- NR1H4 | c.273C>A p.Y91* (on ENST00000551379 / NM_001206993.2; = p.Y81* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99499942; called by muse, mutect2
- NR1H4 | c.275C>G p.S92C (on ENST00000551379 / NM_001206993.2; = p.S82C on NM_005123.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV51853324; called by muse, mutect2
- NSD1 | c.4849G>A p.E1617K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV61778308; called by muse, mutect2, varscan2
- NTMT1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1311297451, COSV52965246, COSV52966053; called by muse, mutect2, varscan2
- NUP85 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55464726; called by muse, mutect2, varscan2
- OAS2 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as rs1279241482, COSV100660054, COSV60802611; called by muse, mutect2, varscan2
- OR13C3 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66165965; called by muse, mutect2, varscan2
- OR13C3 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs1330501019, COSV66165969; called by muse, mutect2
- OR8S1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59600131; called by muse, mutect2, varscan2
- PAXIP1 | c.3175C>G p.Q1059E | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66898573; called by muse, mutect2, varscan2
- PDZD2 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56862024; called by muse, mutect2, varscan2
- PGAM2 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV51978651; called by muse, mutect2
- PHF8 | c.940C>G p.L314V (on ENST00000357988 / NM_001184896.1; = p.L278V on NM_015107.3) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV57683172; called by muse, mutect2, varscan2
- PHRF1 | c.4870G>A p.V1624M (on ENST00000264555 / NM_001286581.2; = p.V1623M on NM_020901.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1315887843, COSV52757566; called by muse, mutect2
- PIKFYVE | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV52243572; called by muse, mutect2
- PIKFYVE | c.3328C>G p.L1110V | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as COSV100009616; called by muse, mutect2
- PLA2G1B | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57679608; called by muse, mutect2
- PLEKHM1 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV101378651; called by muse, mutect2
- PMFBP1 | c.1921G>A p.E641K (on ENST00000537465; = p.E636K on NM_031293.3) | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52826329; called by muse, mutect2
- PRDM7 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57987048; called by muse, mutect2
- PRKAA1 | c.1093C>T p.H365Y | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.055); catalogued as COSV57184545; called by muse, mutect2
- PRKDC | c.3485C>G p.S1162* | Nonsense Mutation (SNP) | VAF 14/177 reads (8%) | catalogued as COSV100038138; called by muse, mutect2
- PRPF6 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53872810; called by muse, mutect2, varscan2
- PRSS12 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs774173802, COSV56604439; called by muse, mutect2, varscan2
- PSMD2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59530414; called by muse, mutect2, varscan2
- PTCHD4 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV59780568; called by muse, mutect2
- PTPRB | c.3097G>T p.E1033* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV54234445, COSV99715512; called by muse, mutect2, varscan2
- RAB22A | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV54830099, COSV54832188; called by muse, mutect2, varscan2
- RAB5B | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV64365018; called by mutect2, varscan2
- RAB9A | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99689664; called by muse, mutect2
- RAD50 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528515; called by muse, mutect2
- RASGEF1B | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1333137721, COSV100021187, COSV52336523; called by muse, mutect2
- RCBTB1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV51635209; called by muse, varscan2
- RELN | c.3736G>C p.D1246H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59011207; called by muse, mutect2, varscan2
- RFC4 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV56217454; called by muse, mutect2, varscan2
- RHOU | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64208713; called by muse, mutect2, varscan2
- RICTOR | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV57124256; called by muse, mutect2
- RIF1 | c.6386C>G p.S2129C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV54618945; called by muse, mutect2
- RPL31 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV51821433; called by muse, mutect2
- RPS6KA2 | c.217-1G>A p.X73_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99690044; called by muse, mutect2
- RREB1 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1326290554, COSV58559935; called by muse, mutect2, varscan2
- RSBN1L | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58509044; called by muse, mutect2
- RSRC2 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV59205276; called by muse, mutect2
- RUNX2 | c.1363C>G p.Q455E (on ENST00000371438; = p.Q433E on NM_001015051.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61842562; called by muse, mutect2, varscan2
- SART3 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.046); catalogued as rs1431737103, COSV57208240, COSV99934482; called by muse, mutect2, varscan2
- SEMA3E | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV57095528; called by muse, mutect2, varscan2
- SEMA6C | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59004542; called by muse, mutect2
- SETDB1 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54979770, COSV54984186; called by muse, mutect2
- SLC23A3 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1205285342, COSV55408117; called by muse, mutect2, varscan2
- SLC25A14 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99502272; called by muse, mutect2
- SLX4 | c.2738G>C p.R913T | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV53565268; called by muse, mutect2
- SMC6 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV61175660; called by muse, mutect2, varscan2
- SMCHD1 | c.5267C>T p.T1756I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV55260370; called by muse, mutect2, varscan2
- SORCS1 | c.3422C>T p.S1141L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53876465; called by muse, mutect2, varscan2
- SORCS3 | c.2144T>C p.M715T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV63795905; called by muse, mutect2, varscan2
- SPAST | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as COSV59515214; called by muse, mutect2, varscan2
- SPG11 | c.7036G>T p.D2346Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55997095; called by muse, mutect2, varscan2
- SRRM2 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57072793, COSV57075432; called by muse, mutect2
- ST13 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53422272; called by muse, mutect2
- STAG2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 11/144 reads (8%) | catalogued as COSV54350913; called by muse, mutect2
- STIL | c.3369G>A p.M1123I | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54551161; called by muse, mutect2
- SUZ12 | c.1202-1G>A p.X401_splice | Splice Site (SNP) | VAF 4/64 reads (6%) | catalogued as rs1441139905, COSV59503927; called by muse, mutect2
- SYN1 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55984600; called by muse, mutect2
- TAS2R3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV56092153; called by muse, mutect2, varscan2
- TCF4 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 14/215 reads (7%) | catalogued as COSV100609090, COSV61907478; called by muse, mutect2
- TEDC2 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV53542669, COSV99563060; called by muse, mutect2
- TEX37 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.113); catalogued as COSV57556082; called by muse, mutect2
- THPO | c.539C>G p.S180C (on ENST00000649095 / NM_001290003.1; = p.S40C on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52609415; called by muse, mutect2, varscan2
- TMEM79 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs143363559; called by muse, mutect2, varscan2
- TP53 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52729268, COSV52968197, COSV53108458; called by muse, mutect2, varscan2
- TRGV2 | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.041); catalogued as rs574364770; called by muse, mutect2, varscan2
- TRIM24 | c.2614G>C p.D872H (on ENST00000343526 / NM_015905.3; = p.D838H on NM_003852.4) | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58973728; called by muse, mutect2, varscan2
- TRIP13 | c.1107G>C p.L369F | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.231); catalogued as COSV51320426, COSV51320774; called by muse, mutect2, varscan2
- TRMO | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64293329, COSV64293725; called by muse, mutect2, varscan2
- TRMT10C | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59306134; called by muse, mutect2, varscan2
- TTC21A | c.2931C>G p.I977M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV57186272; called by muse, mutect2
- USH2A | c.10840G>C p.E3614Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV100228187; called by muse, mutect2
- USH2A | c.9489G>C p.Q3163H | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV56388245; called by muse, mutect2
- UTP6 | c.1022C>G p.S341* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99911767; called by muse, mutect2
- VCP | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV62721054; called by muse, mutect2, varscan2
- VIT | c.1095G>C p.Q365H (on ENST00000389975 / NM_001177969.1; = p.Q380H on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.954); catalogued as COSV101007238, COSV64897289; called by muse, mutect2
- VPS13B | c.7290G>C p.L2430F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1384176527, COSV62146421; called by muse, mutect2, varscan2
- WDFY3 | c.2444C>T p.S815F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99881724; called by muse, mutect2
- WNK1 | c.4600C>G p.H1534D (on ENST00000315939 / NM_018979.4; = p.H1287D on NM_014823.3) | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV60036823; called by muse, mutect2, varscan2
- XPC | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53205753; called by muse, mutect2
- YES1 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV58850864; called by muse, mutect2
- ZBTB45 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100657656; called by mutect2, varscan2
- ZFP57 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as COSV100971787; called by muse, mutect2
- ZNF142 | c.4374C>A p.F1458L (on ENST00000411696 / NM_001379660.1; = p.F1258L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV68744231; called by muse, mutect2
- ZNF155 | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54207239; called by muse, mutect2
- ZNF197 | c.2343G>C p.K781N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV60360870; called by muse, mutect2, varscan2
- ZNF208 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.096); catalogued as rs879078150, COSV68108495; called by muse, mutect2
- ZNF256 | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56598020; called by muse, mutect2
- ZNF35 | c.781C>G p.Q261E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV56076886; called by muse, mutect2, varscan2
- ZNF563 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.229); catalogued as COSV53371015; called by muse, mutect2
- ZNF600 | c.1208G>C p.R403T | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV57743378; called by muse, mutect2, varscan2
- ZNF600 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV57743391; called by muse, mutect2, varscan2
- ZNF606 | c.561C>G p.H187Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62047280; called by muse, mutect2
- ZNF607 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV67697247; called by muse, mutect2
- ZNF622 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58074516; called by muse, mutect2
- ZNF699 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as rs759617724, COSV58026046; called by muse, mutect2, varscan2
- ZNF8 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV52188310; called by muse, mutect2
- ZSCAN2 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57572339; called by muse, mutect2
- LOXL3 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR56B4 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHKA2 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); called by muse, mutect2
- UHRF2 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); called by muse, mutect2
- AAAS | c.831G>A p.E277= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV52933313; called by muse, mutect2, varscan2
- AC011462.1 | c.345C>G p.V115= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV54197934; called by muse, mutect2, varscan2
- ADAM10 | c.783C>T p.D261= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV53052387; called by muse, mutect2
- ADGRA2 | c.1137C>T p.S379= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV59444667; called by muse, mutect2
- AGK | c.1268G>A p.*423= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1461844226, COSV100814511; called by muse, mutect2, varscan2
- AHNAK | c.14292C>T p.I4764= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as rs370827020; called by muse, mutect2
- AL359922.1 | c.426C>T p.L142= | Silent (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- APEH | c.390C>G p.L130= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV56528839; called by muse, mutect2, varscan2
- ARHGEF6 | c.2175C>G p.V725= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV51692435; called by muse, mutect2
- ARMC8 | c.669G>A p.S223= (on ENST00000469044 / NM_001363941.2; = p.S209= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs1377991353, COSV61768764; called by muse, mutect2
- ATP1A4 | c.2334G>A p.L778= | Silent (SNP) | VAF 123/327 reads (38%) | catalogued as rs1203986716, COSV63626946; called by muse, mutect2, varscan2
- BCORL1 | c.1596C>T p.S532= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as rs184916457, COSV54399049, COSV54407665; called by muse, mutect2, varscan2
- BCORL1 | c.2521C>T p.L841= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV54399101; called by muse, mutect2
- BCORL1 | c.2766C>T p.V922= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV54399116; called by muse, mutect2, varscan2
- CCT7 | c.60C>T p.P20= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs938456218, COSV57822661; called by muse, mutect2
- CD109 | c.2466C>T p.I822= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs1448617968, COSV54646796; called by muse, mutect2
- CD209 | c.1152C>T p.C384= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as COSV52655066; called by muse, mutect2, varscan2
- CENPF | c.999G>A p.E333= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65275984; called by muse, mutect2
- CHTF18 | c.2610G>A p.G870= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV50210637; called by muse, mutect2
- CPA1 | c.618C>T p.F206= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV50570933; called by muse, varscan2
- CPA1 | c.933C>G p.L311= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV50570970, COSV50575253; called by muse, mutect2
- CSMD2 | c.2457C>T p.I819= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs544713250, COSV53924898, COSV53936875; called by mutect2, varscan2
- DAAM2 | c.1725C>T p.L575= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs777314846, COSV51342583; called by muse, mutect2, varscan2
- DHPS | c.147C>T p.F49= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2
- DISP3 | c.1428G>A p.L476= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99607157; called by muse, mutect2
- DOP1B | c.3615C>T p.L1205= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs200377583, COSV101214931, COSV67693871; called by muse, mutect2, varscan2
- DPP9 | c.2163G>C p.L721= (on ENST00000598800; = p.L750= on NM_139159.5) | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV53592058; called by muse, mutect2
- EZH2 | c.855C>T p.F285= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV57455605; called by muse, mutect2, varscan2
- FGF12 | c.186G>A p.V62= | Silent (SNP) | VAF 24/218 reads (11%) | catalogued as COSV53171687; called by muse, mutect2, varscan2
- FILIP1 | c.303G>A p.L101= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV52733440; called by muse, mutect2
- FREM2 | c.1071C>T p.F357= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV54841851; called by muse, mutect2, varscan2
- GAS2L1 | c.1419G>A p.Q473= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1479556562, COSV99329363; called by muse, mutect2
- GFPT2 | c.1041T>C p.F347= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV53809483; called by muse, mutect2, varscan2
- GNAI2 | c.495G>A p.Q165= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99806780, COSV99807226; called by muse, mutect2
- HNMT | c.234C>T p.Y78= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV54508554; called by muse, mutect2, varscan2
- HSPB8 | c.498C>T p.I166= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as rs1300830983, COSV56138686, COSV56139499; called by muse, mutect2
- ID1 | c.57G>A p.L19= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV65888671; called by muse, mutect2, varscan2
- IFNA17 | c.525C>G p.L175= | Silent (SNP) | VAF 31/446 reads (7%) | catalogued as rs779618135, COSV69738200; called by muse, mutect2
- IFNA7 | c.402G>C p.L134= | Silent (SNP) | VAF 22/362 reads (6%) | catalogued as COSV53331512; called by muse, mutect2
- IL13 | c.411G>A p.K137= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100449372; called by muse, mutect2
- JUP | c.1749C>T p.L583= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs782751412, COSV60278639; called by muse, mutect2, varscan2
- KCNH6 | c.375C>T p.F125= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV59004603; called by muse, mutect2, varscan2
- KLRK1 | c.201C>T p.F67= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV53698916; called by muse, mutect2
- LUC7L | c.630C>T p.F210= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs898594506, COSV53457917; called by muse, mutect2, varscan2
- MAFF | c.132C>G p.L44= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58299257; called by muse, mutect2, varscan2
- MEI1 | c.3027C>G p.L1009= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV55901430, COSV55904212; called by muse, mutect2, varscan2
- MRPL37 | c.489C>A p.L163= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV60322023; called by muse, mutect2, varscan2
- MUC16 | c.29802C>A p.I9934= | Silent (SNP) | VAF 17/219 reads (8%) | catalogued as rs1036292428, COSV67442235; called by muse, mutect2
- NARS1 | c.1131C>T p.L377= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as rs1246186704, COSV56877204; called by muse, mutect2
- NEXMIF | c.528G>T p.T176= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV50042382; called by muse, mutect2, varscan2
- NIBAN1 | c.264G>A p.E88= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV62285593; called by muse, mutect2, varscan2
- OGFOD2 | c.1047C>T p.L349= (on ENST00000228922 / NM_001304833.1; = p.L289= on NM_024623.3) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99758194; called by muse, mutect2, varscan2
- OR56A4 | c.960G>A p.R320= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1487350722, COSV58109742; called by muse, mutect2, varscan2
- OR9A2 | c.297C>G p.L99= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs1478305262; called by muse, mutect2
- PDZD2 | c.753G>A p.E251= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV56852234; called by muse, mutect2, varscan2
- PIGU | c.1089C>T p.I363= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs760833968, COSV54162486; called by muse, mutect2
- PIP5KL1 | c.735C>A p.L245= (on ENST00000388747 / NM_001135219.2; = p.L42= on NM_173492.1) | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV55944794; called by muse, mutect2
- PLIN3 | c.324C>T p.P108= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55735813; called by muse, mutect2, varscan2
- PNPLA7 | c.381G>A p.V127= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV53000843; called by muse, mutect2, varscan2
- PRAME | c.156C>T p.L52= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV67161847; called by muse, mutect2, varscan2
- PRPF18 | c.957G>A p.K319= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV66074986; called by muse, mutect2
- PRPS1 | c.105C>T p.F35= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV65055109; called by muse, mutect2, varscan2
- PRR3 | c.399C>G p.L133= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV64835328; called by muse, mutect2, varscan2
- PSPH | c.21G>C p.L7= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99303960; called by muse, mutect2
- RRP8 | c.1164G>A p.L388= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV54449503; called by muse, mutect2
- SACS | c.5488C>T p.L1830= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV66542240; called by muse, mutect2, varscan2
- SATB2 | c.2022G>A p.G674= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV53486561; called by muse, mutect2
- SESN3 | c.1478G>A p.*493= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99565198; called by mutect2, varscan2
- SIAH2 | c.744C>T p.I248= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs751929587, COSV57262429; called by muse, mutect2, varscan2
- SLC38A1 | c.1293C>T p.F431= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs267603472, COSV67062939; called by muse, varscan2
- SLC6A3 | c.1524C>T p.I508= | Silent (SNP) | VAF 13/166 reads (8%) | catalogued as rs745668378, COSV54365539; called by muse, mutect2
- SLC9A4 | c.2079C>T p.F693= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54835480; called by muse, mutect2
- SLC9A8 | c.627C>T p.F209= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100846355, COSV64288607; called by muse, mutect2, varscan2
- SSH1 | c.762C>T p.L254= | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as COSV100425618, COSV58457388; called by muse, mutect2
- STARD7 | c.978G>A p.K326= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV61526134; called by muse, mutect2, varscan2
- STC2 | c.771T>A p.G257= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV54180569; called by muse, mutect2
- STX10 | c.261G>A p.E87= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52848286; called by muse, mutect2, varscan2
- TCF20 | c.4983G>A p.V1661= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV59493120; called by muse, mutect2
- TCF7L1 | c.1038G>A p.V346= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56399864; called by muse, mutect2, varscan2
- TMEM37 | c.555C>T p.I185= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV50028925; called by muse, mutect2
- TNFSF13 | c.99G>A p.L33= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV53432969; called by muse, mutect2, varscan2
- TTN | c.74103G>A p.V24701= (on ENST00000591111; = p.V17277= on NM_003319.4) | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs1559358175, COSV59863478, COSV60147320; called by muse, mutect2
- UGGT1 | c.3591C>A p.L1197= | Silent (SNP) | VAF 25/210 reads (12%) | catalogued as COSV52137399, COSV52140363; called by muse, mutect2, varscan2
- UHRF1 | c.249C>G p.T83= (on ENST00000612630 / NM_001290050.1; = p.T96= on NM_013282.4) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs373501649; called by muse, mutect2, varscan2
- USF3 | c.4077G>A p.L1359= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV57074349; called by muse, mutect2
- ZBTB49 | c.729C>T p.F243= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV61925329; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1236C>T p.I412= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs374328599; called by muse, mutect2
- ZNF350 | c.831C>G p.L277= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV54709383; called by muse, mutect2, varscan2
- ZNF7 | c.1584C>G p.L528= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV57384198; called by mutect2, varscan2
- ZSWIM4 | c.2559C>T p.L853= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as rs1399766012, COSV54323251; called by muse, mutect2
- ATP11AUN | n.1064T>C | RNA (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- CR1 | c.487+11957G>A | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65459377; called by muse, mutect2, varscan2
- RNF216 | c.202-15G>A | Intron (SNP) | VAF 19/175 reads (11%) | catalogued as COSV66291175; called by muse, mutect2, varscan2
- SIAH1 | c.-3G>A | 5'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100764633, COSV63210898; called by muse, mutect2, varscan2
- SUGCT | c.1090-65318C>T | Intron (SNP) | VAF 6/98 reads (6%) | catalogued as COSV59336789; called by muse, mutect2
